Gene-level copy-number profile of tumor specimen ALCH-B2UN-TTP1-A from ALCHEMIST case ALCH-B2UN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.2 years (23,801 days).
Specimen ALCH-B2UN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 425acdba-3baf-476a-aa32-44cbfd856ad1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2UN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/b5abea2e-ac88-49e9-ad6b-f8748f62f9c1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 640; copy number 1: 15,373; copy number 2: 39,880; copy number 3: 2,918; copy number 4: 71; copy number 5: 7; copy number 6: 4; copy number 8: 3; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 107 genes in 38 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,318,114–8,344,167, 2 genes: SLC45A1, Y_RNA.
- chr2:20,200,797–20,241,046, 2 genes: SDC1, DRG1P1.
- chr2:132,253,154–132,294,377, 4 genes (within-gene range 0–2): RNA5-8SP5, MIR663B, CDC27P1, AC097532.1.
- chr3:12,673,699–12,673,883, 1 gene: CRIP1P1.
- chr3:90,261,414–90,261,708, 1 gene: HSPE1P19.
- chr4:25,529,177–25,623,601, 3 genes: AC105290.1, RNU7-126P, AC092436.1.
- chr4:151,099,624–151,104,642, 2 genes (within-gene range 0–2): RPS3A, SNORD73B.
- chr4:151,103,827–151,103,891, 1 gene (within-gene range 0–2): SNORD73A.
- chr6:34,576,258–34,576,656, 1 gene: IFITM3P3.
- chr6:73,322,837–73,323,450, 1 gene: SDCBP2P1.
- chr6:85,731,371–85,869,464, 5 genes: AL355615.1, SMIM11P1, RNU4-72P, Y_RNA, AL450338.1.
- chr7:2,631,986–2,664,802, 1 gene: TTYH3.
- chr7:62,275,361–63,060,084, 4 genes: AC128676.1, RNU6-417P, AC069285.2, AC069285.3.
- chr7:139,448,740–139,483,673, 2 genes: RNU6-911P, KLRG2.
- chr7:152,463,786–152,465,549, 1 gene: LINC01003.
- chr8:33,580,210–33,600,023, 2 genes: RN7SL621P, DUSP26.
- chr8:33,641,581–33,641,939, 1 gene (within-gene range 0–2): BUD31P1.
- chr8:43,539,137–43,674,591, 5 genes: AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1.
- chr9:33,449,755–33,473,930, 3 genes: AL356218.1, NOL6, MIR6851.
- chr9:40,883,634–40,883,763, 1 gene: AL353626.2.
- chr9:69,428,248–69,428,721, 1 gene (within-gene range 0–1): AL355140.1.
- chr10:38,783,004–38,783,108, 1 gene: AL590623.1.
- chr11:48,880,111–48,908,946, 4 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr11:50,298,579–54,725,816, 14 genes: LINC02750, AC024405.2, AC024405.1, OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.
- chr12:37,575,587–38,087,392, 3 genes: ZNF970P, AK6P2, CLUHP8.
- chr14:24,573,518–24,576,250, 1 gene: CTSG.
- chr14:24,606,480–24,609,699, 1 gene (within-gene range 0–2): GZMH.
- chr14:67,386,984–67,412,167, 1 gene: PLEK2.
- chr15:78,382,573–78,383,155, 1 gene: AC011270.1.
- chr16:68,630,223–68,630,968, 2 genes: AC126773.1, AC126773.2.
- chr16:68,644,248–68,651,948, 2 genes (within-gene range 0–2): AC126773.4, AC126773.5.
- chr16:75,204,103–75,228,197, 3 genes (within-gene range 0–2): CTRB2, CTRB1, AC009078.2.
- chr17:2,712,309–3,037,741, 7 genes (within-gene range 0–2): AC005696.1, AC005696.4, CCDC92B, MIR1253, hsa-mir-1253, RAP1GAP2, AC015921.1.
- chr17:46,762,506–47,049,932, 9 genes (within-gene range 0–1): WNT3, WNT9B, LINC01974, AC005670.1, RNU6ATAC3P, GOSR2, AC005670.2, MIR5089, RPRML.
- chr19:11,483,427–11,529,172, 6 genes (within-gene range 0–1): ZNF653, MIR7974, ECSIT, RN7SL833P, AC008481.2, AC008481.1.
- chr19:24,146,701–24,163,425, 2 genes: AC073534.2, AC073534.1.
- chr19:49,038,479–49,050,846, 5 genes: NTF6B, AC008687.5, CGB5, CGB8, AC008687.6.
- chr21:12,999,676–13,016,692, 1 gene: AP001464.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:39,072,767–39,508,885, 12 genes, copy number 5–9: CNTNAP3, RBM17P1, AL353729.2, AL353729.1, RN7SL640P, SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3.
- chr10:124,397,303–124,418,976, 1 gene, copy number 6: OAT.
- chr22:18,906,028–18,947,732, 3 genes, copy number 6 (within-gene range 2–6): DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 13,070. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
